Somatic mutation profile of tumor specimen MP2PRT-PAPWJS-TMP1-A (aliquot MP2PRT-PAPWJS-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPWJS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,886 days).
Specimen MP2PRT-PAPWJS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ab8c957-3e88-4c9e-b559-af482df3686a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWJS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWJS-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/918513dd-145c-4bae-9a09-84cbcd521ba7

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 149/338 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3781G>A p.V1261M | Missense Mutation (SNP) | VAF 193/382 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs756405833, COSV60681529; called by muse, mutect2, varscan2
- CRTC1 | c.857C>G p.T286R | Missense Mutation (SNP) | VAF 268/539 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58719618; called by muse, mutect2, varscan2
- FGFR2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 206/616 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs200766273, COSV60646540, COSV60647757; called by muse, mutect2, varscan2
- SPRR2A | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 182/463 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.04); catalogued as rs902317665; called by muse, mutect2, varscan2
- ADIPOR1 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNMT3L | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 138/560 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- PLXNA4 | c.1755G>A p.P585= | Silent (SNP) | VAF 124/257 reads (48%) | catalogued as rs749277155, COSV58142069; called by muse, mutect2, varscan2
- TMEM233 | c.261C>T p.I87= | Silent (SNP) | VAF 176/366 reads (48%) | catalogued as rs973288311; called by muse, mutect2
